Somatic mutation profile of tumor specimen TCGA-AB-2900-03A (aliquot TCGA-AB-2900-03A-01W-0733-08) from TCGA case TCGA-AB-2900, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia without maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.2 years (25,627 days).
Specimen TCGA-AB-2900-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa9eff0d-437c-424e-aef8-2a289267f880.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2900-11A (Solid Tissue Normal), aliquot TCGA-AB-2900-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e991bec7-e9cf-48e7-a315-c794973dd37b

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNT1 | c.274T>A p.S92T (on ENST00000488444; = p.S111T on NM_020822.3) | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.21); PolyPhen benign (0.025); catalogued as COSV53702598; called by muse, mutect2, varscan2
- SPEN | c.797C>G p.T266R | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.462); catalogued as COSV65362873; called by muse, mutect2, varscan2
